FM case AD11926 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/9a19451f-8c86-4faf-bdd8-1112e8f2713d

Male, 42.4 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
